Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A242, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A242-01A (Primary Tumor).

OC#: TSS #:

Procurement Date: 3/18/2011 Laterality: NA

Path Report: THYROID CARCINOMA CHECKLIST

1. Tumor type: Papillary.
2. Tumor location: Left lobe and isthmus.
3. Tumor multicentricity: Single focus
4. Tumor size: 1.8 x 1.2 cm.
5. Extrathyroid extension: Yes
6. Surgical margins: Involved by tumor.
7. Angiolymphatic invasion: Yes
8. Lymph nodes: Negative for neoplasm.
9. TNM: T3 N0 Mx

1CD-0-3
Carcinoma, papillary thyroid 8260/3
Site: thyroid, NOS C73.9
for 4/22/11

Source: NCI Genomic Data Commons file d96b6198-eaba-4e92-883d-2ce579601a7d (TCGA-E8-A242.09B63616-A074-472B-80AA-FCBE71863FA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).